CCDI case PBCHAP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e5e9fd3b-9066-4fcc-b132-3a3bbfa7d1ee

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.8 years (5,388 days).

Biospecimens (3 samples)
- Sample 0DRRTU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRRU2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRRUJ: Tissue type: Tumor; Specimen type: Solid Tissue.
